Somatic mutation profile of tumor specimen 0DVR8G from CCDI case PBCNDS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.9 years (3,266 days).
Specimen 0DVR8G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 162e6fae-7025-4040-932a-44f6df750277.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVR5Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/187c5265-8ca7-45d7-bdc6-b7482838cc8f

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD3A | c.1262A>G p.Y421C | Missense Mutation (SNP) | VAF 25/335 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387798456; called by muse, mutect2, varscan2
- ATP5PB | c.514A>G p.N172D | Missense Mutation (SNP) | VAF 138/335 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.72); catalogued as rs758823326; called by muse, mutect2, varscan2
- CDHR3 | c.2464C>G p.R822G | Missense Mutation (SNP) | VAF 272/417 reads (65%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58415943, COSV58417273; called by muse, mutect2, varscan2
- HAUS5 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 114/258 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs759341983; called by muse, mutect2, varscan2
- CA1 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 48/436 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CHD4 | c.347A>G p.K116R | Missense Mutation (SNP) | VAF 149/343 reads (43%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CMYA5 | c.8282A>T p.K2761I | Missense Mutation (SNP) | VAF 156/394 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.403); called by mutect2, varscan2
- EPPK1 | c.4246C>A p.Q1416K | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2
- OR1Q1 | c.318C>G p.C106W | Missense Mutation (SNP) | VAF 35/498 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.339); called by muse, mutect2
- PPFIA2 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 167/344 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SH2B3 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEKT3 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 188/193 reads (97%) | SIFT tolerated (0.14); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- ZBTB1 | c.1945C>G p.H649D | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2
- ATXN1 | c.1503G>A p.A501= | Silent (SNP) | VAF 18/300 reads (6%) | catalogued as rs201987168, COSV104392099; called by muse, mutect2
- ZNF318 | c.6804C>T p.A2268= | Silent (SNP) | VAF 14/301 reads (5%) | catalogued as rs1426433861; called by muse, mutect2
- EIF3L | c.34-61G>A | Intron (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- GRM8 | c.*91T>C | 3'UTR (SNP) | VAF 6/196 reads (3%) | called by muse, mutect2
- PSME3 | c.543-49G>A | Intron (SNP) | VAF 18/408 reads (4%) | catalogued as rs1159308750; called by muse, mutect2
